Somatic mutation profile of tumor specimen TARGET-10-PARDBT-09A (aliquot TARGET-10-PARDBT-09A-01D) from TARGET case TARGET-10-PARDBT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,537 days).
Specimen TARGET-10-PARDBT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54b549a1-1b6f-4715-91b9-86b5665fd64f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDBT-10A (Blood Derived Normal), aliquot TARGET-10-PARDBT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79951802-9d9d-4b6b-aad1-0d72bae79992

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'Flank 2, Intron 2, Frame Shift Del 1, Splice Region 1, 5'UTR 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGSF23 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.911); catalogued as rs745571129; called by muse, mutect2, varscan2
- KRTAP19-3 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs543308267, COSV61854565; called by muse, mutect2, varscan2
- OCIAD1 | c.58+9_58+12del | Splice Region (DEL) | VAF 14/38 reads (37%) | catalogued as rs762084803; called by pindel, varscan2
- PGF | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs200980724, COSV53125700, COSV99462655; called by muse, mutect2, varscan2
- VWC2L | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs753295197, COSV56964997, COSV56981058; called by muse, mutect2, varscan2
- ANK3 | c.276G>C p.E92D | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP4R4 | c.607A>G p.K203E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- SEPTIN10 | c.220del p.E74Kfs*9 | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- SSTR2 | c.612G>A p.W204* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- TANGO6 | c.1136T>A p.L379Q | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SHANK1 | c.4995G>A p.P1665= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1437095005, COSV53249914; called by muse, mutect2, varscan2
- CRISP3 | chr6:49728632 A>G | 3'Flank (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- IQCF3 | c.66+115C>A | Intron (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- MTX1 | chr1:155218026 T>A | 3'Flank (SNP) | VAF 50/120 reads (42%) | called by muse, mutect2, varscan2
- NKIRAS2 | c.-419dup | 5'UTR (INS) | VAF 18/38 reads (47%) | catalogued as rs1210883513; called by mutect2, varscan2
- RRP12 | c.-138+6626C>G | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
